Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SO, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SO-01A (Primary Tumor).

[page 1 of 3]
Result Type: Surgical Pathology Report

Result Date:

Performed By:

**Encounter
info:**

Surgical Pathology Report

Final

ICD-O-3
Carcinoma, papillary renal cell
Site @ Kidney NOS 8260/3
C64.9
JW 10/4/13

Surgical Pathology Report

Clinic Number: Name:

Requested By:

DIAGNOSIS:

A. Ascending and proximal transverse colon, appendix:
Specimen: Terminal ileum, cecum, ascending and transverse colon.
Procedure: Right hemi- and transverse colectomy.
Tumor site: Ascending colon, 12 cm from ileocecal valve.
Tumor size: 3.0 cm in greatest dimension.
Tumor histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated (grade 2 of 3).
Microscopic tumor extension: Invasive adenocarcinoma, extends into the submucosa. No evidence of carcinoma penetrating into the underlying muscularis propria.
Margins: Proximal small bowel and distal colonic margins; negative for tumor.
Distance to mesorectal margin: Not applicable.
Lymph-vascular invasion: Not identified.
Perineural invasion: Not identified.
Tumor deposits (discontinuous extramural extension): Not present.
Macroscopic completeness of mesorectum (if applicable): Not applicable.
Lymph nodes: A total of twenty-two regional lymph nodes, negative for metastatic adenocarcinoma (0/22).
Response to treatment: Not applicable.
Additional findings: Separate inflammatory polyp, 0.6 cm in greatest dimension, distal to the main tumor mass. Appendix, with fibrous obliteration.
Pathologic staging: pT1, pN0.
Ancillary testing: Not performed.
Block(s) containing malignancy suitable for further testing: Block A5.

B. Left kidney tumor:
Procedure/laterality: Left partial nephrectomy.
Histologic type: Papillary renal cell carcinoma, with eosinophilic cytoplasm.
Nuclear grade (Fuhrman, 1-4): 2 of 4.
Tumor size: 7.0 cm in greatest dimension.
Tumor site: Upper pole.
Tumor focality: Unifocal.
Sarcomatoid features: Not present.
Tumor necrosis: Not present.

[page 2 of 3]
Microscopic tumor extension:

Extension into perinephric tissue: Not present.
Extension beyond Gerota's fascia: Not present.
Extension into renal sinus: Not present.
Extension into renal vein: Not present.
Extension into collecting system: Not present.
Extension into adrenal gland (if applicable): Not applicable.

Surgical margins: Fatty soft tissue margins; negative for tumor.
Lymph-vascular invasion: Not identified.

Lymph nodes: None present.

Pathologic findings in nonneoplastic kidney: No specific pathologic features.

Pathologic staging: pT1b, pNX.

Biorepository sample (if applicable): Representative section of tumor and normal kidney are shown on block B6.

Block(s) containing malignancy suitable for additional testing: B4.

DIAGNOSIS COMMENT:

Selected slides of the colectomy and nephrectomy specimens reviewed with .

CLINICAL INFORMATION:

Hepatic flexure cancer and left kidney renal cell carcinoma.

SPECIMEN(S):

A:Ascending and proximal transverse colon, appendix
B:Lt kidney tumor

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

Intraoperative Pathologist(s):

A. Ascending proximal transverse colon and appendix, gross consultation: Margins grossly clear. Tumor identified (approximately 3 cm). Relatively flat polyp identified more distally.

B. Left kidney tumor, frozen section diagnosis: Papillary renal cell carcinoma, no sarcomatoid features.

GROSS DESCRIPTION:

Performed by Pathologist's Assistant

A. Received fresh labeled and "ascending and proximal transverse colon, appendix."

Specimen: Terminal ileum, cecum, ascending and transverse colon.

Procedure: Right hemi- and transverse colectomy.

Dimensions: 5.5 cm of terminal ileum and 50 cm of large bowel.

Tumor site: Ascending colon, 12 cm distal to ileocecal valve.

Tumor configuration: Flat, granular, pink-tan.

Tumor size: 3 x 2.5 x 0.5 cm.

Tumor distance to nearest margin: Proximal, 17 cm.

Distance to mesorectal margin (if applicable): Not applicable.

Macroscopic completeness of mesorectum: Not applicable.

Tumor extension into fat: Not grossly identified.

[page 3 of 3]
Tumor extension to inked free surface: No.
Tumor perforation: No.
Tumor deposits in fat: No.
Additional mass/polyp(s): Yes; 0.6 x 0.4 x 0.3 cm situated 8 cm distal to the main tumor.
Lymph nodes: Twenty-three possible lymph nodes from 0.2 cm to 0.8 cm.
Gross notes:
Additional findings: A grossly unremarkable 5 x 0.6-cm appendix encased by slightly hemorrhagic fat.

Block key for specimen A: A1) sample of each surgical margin; A2-A5) entire main tumor; A6) polyp; A7) appendix; A8) eight lymph nodes; A9) four lymph nodes; A10) eight lymph nodes; A11) three lymph nodes.

B. Received fresh labeled and "left kidney tumor."

Procedure: Partial nephrectomy.

Specimen laterality: Left.

Tumor site: Upper pole.

Tumor size: 7 x 5 x 5 cm.

Tumor focality: Unifocal.

Gross extent of tumor:

Extension into perinephric tissue: Absent.

Extension beyond Gerota's fascia: Absent.

Extension into renal sinus: Absent.

Extension into renal vein: Absent.

Extension into collecting system: Absent.

Adrenal gland: Not identified.

Gross notes:

Gross tumor characteristics: Soft, gray-brown, predominately solid.

Kidney weight: 325 g with fat, 135 g without fat.

Specimen dimensions: Overall 11 x 8 x 7 cm.

Distance to margin: 0.3 cm grossly from parenchymal margin.

Lymph nodes: None identified.

Inking details: The parenchymal margin and the Gerota's fascia surface are inked blue.

Biorepository sample submitted: Yes, see block key.

Block key for specimen B: B1) Frozen section sample of tumor; B2-B4) additional samples of tumor; B5) inked fatty soft tissue margin; B6) mirror images of biorepository sample (normal and tumor),

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 670f4c5b-a2f2-45c1-a888-a48c213b2bfc (TCGA-SX-A7SO.37B70EEA-86D4-4373-820D-F42F046B8B02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).